Gene-level copy-number profile of tumor specimen TCGA-BC-A10S-01A from TCGA case TCGA-BC-A10S, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 81.7 years (29,842 days).
Specimen TCGA-BC-A10S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c6a7246f-e68d-4215-9e54-d098cea751b4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A10S-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2241a1af-f3d1-48c3-9e93-da31aaf33c54

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,325; copy number 1: 9,697; copy number 2: 45,409; copy number 3: 52; copy number 4: 37; copy number 5: 111; copy number 6: 90; copy number 7: 1,534; copy number 8: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A10S-01A-22D-A12Y-01): tumor purity 0.22, ploidy 3.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 945 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr5:7,239,781–7,240,018, 1 gene: Metazoa_SRP.
- chr6:160,773,988–160,783,214, 1 gene: AL109933.3.
- chr8:213,186–43,674,591, 942 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,740 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–147,003,618, 111 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:150,584–202,897, 5 genes, copy number 8: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7 (broad region; genes not listed).
- chr14:105,764,503–106,309,666, 90 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,682. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
